Somatic mutation profile of tumor specimen TCGA-DU-A76K-01A (aliquot TCGA-DU-A76K-01A-11D-A33T-08) from TCGA case TCGA-DU-A76K, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 87.0 years (31,776 days).
Specimen TCGA-DU-A76K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e6fa8df-0dc0-4a00-9342-fda3893b6238.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-A76K-10A (Blood Derived Normal), aliquot TCGA-DU-A76K-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6127ae33-1ea5-42a4-aa18-e8b64d64ec1e

The open-access MAF lists 52 somatic variants for this specimen: 41 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 10, Frame Shift Del 2, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH16A1 | c.1189G>A p.V397M | Missense Mutation (SNP) | VAF 85/446 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as COSV99512963; called by muse, mutect2, varscan2
- AMPD1 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 16/308 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs147972392, COSV62415349; called by muse, mutect2
- ATCAY | c.940G>A p.V314I | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.044); catalogued as rs1214367792, COSV100008803; called by muse, mutect2, varscan2
- BRCA1 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs144792613, COSV58793068; ClinVar: uncertain significance / conflicting interpretations of pathogenicity / not provided; called by muse, mutect2, varscan2
- C1QTNF1 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs769162624, COSV100189980; called by muse, mutect2, varscan2
- CDH23 | c.7810G>A p.V2604I | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.062); catalogued as rs560143693, COSV99821329; called by muse, varscan2
- DNAH12 | c.89_90del p.I30Rfs*3 | Frame Shift Del (DEL) | VAF 62/263 reads (24%) | catalogued as rs1346215376; called by mutect2, pindel, varscan2
- DOP1B | c.3563C>T p.A1188V | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.23); catalogued as COSV101215461; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2330C>T p.T777M | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749290262, COSV62567043; called by muse, mutect2, varscan2
- EPHB6 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 123/553 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.748); catalogued as rs763788542, COSV101235979; called by muse, mutect2, varscan2
- FER1L6 | c.2236G>A p.A746T | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs762990859, COSV67552665; called by muse, mutect2, varscan2
- FFAR3 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 78/667 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs767171390, COSV59909838; called by muse, mutect2, varscan2
- FMNL1 | c.685G>A p.V229I | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as rs781402859, COSV58955672; called by muse, mutect2, varscan2
- FUS | c.407A>G p.Y136C | Missense Mutation (SNP) | VAF 64/267 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99568674; called by muse, mutect2, varscan2
- HLA-DMB | c.50G>T p.G17V | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV101186833; called by muse, mutect2, varscan2
- KIAA1549 | c.3473C>T p.P1158L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99650923; called by muse, mutect2
- KRTAP4-2 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 72/224 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs1187811274, COSV66658702; called by muse, mutect2
- LIPI | c.1219A>G p.I407V | Missense Mutation (SNP) | VAF 112/241 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.169); catalogued as COSV100753752; called by muse, mutect2, varscan2
- MMP16 | c.1291G>C p.G431R | Missense Mutation (SNP) | VAF 29/260 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99688629, COSV99689492; called by muse, mutect2, varscan2
- MTMR1 | c.593A>G p.E198G | Missense Mutation (SNP) | VAF 61/114 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.768); catalogued as COSV100953957; called by muse, mutect2, varscan2
- MYO1C | c.2812C>T p.R938W (on ENST00000648651 / NM_001080779.2; = p.R903W on NM_033375.5) | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761228547, COSV100704382; called by muse, mutect2, varscan2
- MYPN | c.884T>C p.I295T | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.881); catalogued as COSV100590044; called by muse, mutect2, varscan2
- OR9A2 | c.892C>T p.R298* | Nonsense Mutation (SNP) | VAF 84/356 reads (24%) | catalogued as rs768111948, COSV100628237, COSV63307007; called by muse, varscan2
- PRPSAP2 | c.319G>A p.V107M | Missense Mutation (SNP) | VAF 57/226 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99264581; called by muse, mutect2, varscan2
- PRSS16 | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 84/325 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as rs369828855; called by muse, mutect2, varscan2
- RAB28 | c.513G>C p.Q171H | Missense Mutation (SNP) | VAF 73/271 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.079); catalogued as COSV99986278; called by muse, mutect2, varscan2
- RASAL1 | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 174/708 reads (25%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.506); catalogued as rs761982604, COSV99921797; called by muse, mutect2, varscan2
- RNF103 | c.1542G>T p.M514I | Missense Mutation (SNP) | VAF 142/520 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99410194; called by muse, mutect2, varscan2
- RTP1 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.741); catalogued as rs372732386; called by muse, mutect2, varscan2
- RTTN | c.2192A>G p.D731G | Missense Mutation (SNP) | VAF 83/264 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.795); catalogued as COSV99732658; called by muse, mutect2, varscan2
- SELE | c.74A>G p.N25S | Missense Mutation (SNP) | VAF 60/186 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV60974127; called by muse, mutect2, varscan2
- SERPINB11 | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 54/195 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs775575015, COSV66956495; called by muse, mutect2, varscan2
- SLC12A1 | c.1244C>A p.T415N | Missense Mutation (SNP) | VAF 107/411 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV100372388; called by muse, mutect2, varscan2
- ST18 | c.250T>A p.L84M | Missense Mutation (SNP) | VAF 140/407 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.131); catalogued as COSV99389851; called by muse, mutect2, varscan2
- TFAP2C | c.115C>G p.L39V | Missense Mutation (SNP) | VAF 51/224 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.433); catalogued as COSV99571547; called by muse, mutect2, varscan2
- TNFRSF11B | c.43T>G p.S15A | Missense Mutation (SNP) | VAF 78/272 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV99816705; called by muse, mutect2, varscan2
- TSPAN5 | c.563C>G p.T188S | Missense Mutation (SNP) | VAF 68/227 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0.026); catalogued as rs962625847, COSV99995546; called by muse, mutect2, varscan2
- USP20 | c.2697G>T p.E899D | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as COSV59613574; called by muse, mutect2
- VPS16 | c.1504G>T p.D502Y | Missense Mutation (SNP) | VAF 13/292 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as rs1262914352, COSV100988504; called by muse, mutect2
- ZNF516 | c.2821G>A p.A941T | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765789208, COSV101487227; called by muse, mutect2, varscan2
- BMI1 | c.363_367del p.D121Efs*5 | Frame Shift Del (DEL) | VAF 69/180 reads (38%) | called by mutect2, pindel, varscan2
- ARL11 | c.168C>T p.H56= | Silent (SNP) | VAF 41/129 reads (32%) | catalogued as rs369494120, COSV56292483; called by muse, mutect2, varscan2
- GPR32 | c.561C>T p.G187= | Silent (SNP) | VAF 37/140 reads (26%) | catalogued as COSV99567237; called by muse, mutect2, varscan2
- LECT2 | c.99C>T p.I33= | Silent (SNP) | VAF 28/360 reads (8%) | catalogued as COSV99191868; called by muse, mutect2
- PDZD4 | c.1167C>T p.V389= | Silent (SNP) | VAF 37/59 reads (63%) | catalogued as COSV99381387; called by muse, mutect2, varscan2
- PRMT6 | c.429A>G p.V143= | Silent (SNP) | VAF 70/231 reads (30%) | catalogued as rs769059268, COSV100791200; called by muse, mutect2, varscan2
- RTBDN | c.492C>A p.R164= (on ENST00000393233 / NM_001270444.1; = p.R196= on NM_031429.2) | Silent (SNP) | VAF 5/90 reads (6%) | catalogued as COSV100530801; called by muse, mutect2
- TCN1 | c.1224C>T p.G408= | Silent (SNP) | VAF 180/589 reads (31%) | catalogued as rs749250733, COSV57254168, COSV57254555; called by muse, mutect2, varscan2
- UBE2H | c.444C>T p.Y148= | Silent (SNP) | VAF 49/232 reads (21%) | catalogued as rs375884538; called by muse, mutect2, varscan2
- UNC45B | c.897G>A p.A299= | Silent (SNP) | VAF 130/378 reads (34%) | catalogued as rs151107152; called by muse, mutect2, varscan2
- ZFR2 | c.1188C>T p.P396= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs752285765, COSV99507467; called by muse, mutect2, varscan2
- HERC2P3 | n.380A>T | RNA (SNP) | VAF 15/151 reads (10%) | called by muse, mutect2, varscan2
